Surgical pathology report (de-identified scan), TCGA case TCGA-52-7622, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-52-7622-01A (Primary Tumor).

[page 1 of 3]
Pathologic Interpretation:

- A. Endobronchial mass superior segment of right lower lobe:
- A few distorted atypical cells present in the actual frozen section slide.
- B. Right lower lobe superior segment bronchial mucosa:
- No malignancy seen.
- C. 6th rib:
- Sections pending.
- D. Station # 7 lymph node:
- Three (3) lymph nodes with no malignancy seen.
- E. Superior segment R L lobe:
- Moderately differentiated squamous cell carcinoma.
- It is 2.0 cm.
- The overlying pleura is free of tumor.
- No vascular invasion.
- One (1) lymph node with no malignancy seen.
- pT1a, N0, MX.
- See Tumor Summary
- F. Station # 8 lymph node:
- One (1) lymph node with no malignancy seen.
- G. Station # 9 lymph node:
- One (1) lymph node with no malignancy seen.
- H. Station # 11 lymph node:
- One (1) lymph node with no malignancy seen.
- I. Intrabronchial lesion:
- Detached carcinoma nests admixed with blood.

Note: "I": The specimen in reality is intrabronchial not intrabronchial.

Tumor Summary:

Specimen Type: Lobe: Right lower lobe

Procedure: Lobectomy

Specimen Integrity: Intact.

Laterality: Right

Tumor Site: Lower lobe

Tumor Size: Dimension: 2.0. Additional dimensions: 2.0 x 1.7 cm.

Tumor Focality: Unifocal

Histologic Type

Histologic Type: Squamous cell carcinoma.

Histologic Grade: Moderately differentiated.

Visceral Pleural Invasion: Not identified.

Tumor Extension: Not identified.

Margins: Uninvolved by invasive carcinoma.

Vascular Margin: Uninvolved by invasive carcinoma.

[page 2 of 3]
Parenchymal Margin: Not applicable
Parietal Pleural Margin: Not applicable
Chest wall Margin: Not applicable.
Other Attached Tissue Margin: Not applicable.
Lymph-Vascular Invasion; Not identified:

Pathologic Staging (pTNM): pT1a, N0, MX

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

Procedures/Addenda
Addendum

Status: Signed Out

Addendum Diagnosis

- C. 6th rib:
- Sections of bone show no carcinoma.

Intraoperative Consultation

- A. Endobronchial mass superior segment of right lower lobe fs: Few abnormal cells suspicious for carcinoma. Diagnostic material is limited.
- B. Right lower lobe superior segment bronchial mucosa No tumor seen.
- E. Superior segment R L lobe Bronchial margin: No carcinoma seen.

Clinical History:

Lung carcinoma

Operation Performed

Bronchoscopy

Pre Operative Diagnosis:

Lung carcinoma

[page 3 of 3]
Specimen(s) Received:

- A: Endobronchial mass superior segment of right lower lobe
- B: Right lower lobe superior segment bronchial mucosa
- C: 6th rib
- D: Station # 7 lymph node
- E: Superior segment R L lobe
- F: Station # 8 lymph node
- G: Station # 9 lymph node
- H: Station # 11 lymph node
- I: Intrabronchial lesion

Gross Description:

- A. Received fresh is a pale tan tissue fragment, 0.3 x 0.2 x 0.2 cm. In toto in one cassette for frozen section.
- B. Received fresh are several pale tan tissue fragments, ranging from 0.1 to 0.2 cm. In toto in one cassette for frozen section.
- C. Received in formalin are two fragments of bone tissue, first one 1.5 x 0.5 x 0.5 cm, second one is 1.5 x 1.5 x 1.5 cm. They are bisected. Submitted in toto in four cassettes for decalcification.
- D. Received in formalin are two ovoid tissue fragments, 1.5 x 1 x 1 cm each. Bisected and submitted in toto in three cassettes as follows:
- 1 An entire lymph node bisected
- 2&3 An entire lymph node bisected half in each cassette
- E. Received fresh is a segment of lung, weighs 39 grams, measuring 11 x 3 x 2.5 cm. The pleural surface is smooth and red-purple. There are two lines of metallic staples. Those areas are inked black. Between both lines of surgical metallic staples there is located bronchus 1 x 1 cm. Cut sections through the specimen there is a well demarcated white focally hemorrhagic nodule, 2 x 2 x 1.7 cm which is in relation with the bronchus and it is present approximately 0.4 cm from bronchial resection margin. The tumor present about 25% of necrosis. The rest of the lung parenchyma is red-brown. No other lesions are grossly identified. Representative sections submitted in five cassettes as follows:
- 1 For frozen section
- 2-5 Tumor and lung parenchyma
- F. Received in formalin is a yellow-red-brown soft tissue fragment, 1.5 x 0.5 x 0.5 cm, bisected. Submitted in toto in one cassette.
- G. Received in formalin is a pale tan tissue fragment, 1 x 0.4 x 0.2 cm. Bisected and submitted in toto in one cassette.
- H. Received in formalin is an ovoid, red-brown tissue fragment, 1.3 x 1 x 0.5 cm. Bisected and submitted in toto in one cassette.
- I. Received in formalin is a red-brown soft tissue fragment, 0.2 x 0.2 x 0.1 cm. In toto in one cassette.

Source: NCI Genomic Data Commons file dabd9641-1ffe-4369-a2ee-75df21ec5799 (TCGA-52-7622.A710001F-DFFD-4277-9FF5-E380D6EC827D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).